MMRF case MMRF_1257 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/089a1abc-aa81-46a2-b02f-f0f78a1b3d84

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 74 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 74.9 years (27,355 days); ISS stage: III; Days to last known disease status: 1,617 days (4.4 years); Days to last follow up: 1,617 days (4.4 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 52 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 29 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 99 days; Days to treatment end: 99 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 100 days; Days to treatment end: 100 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 905 days (2.5 years); Days to treatment end: 1,214 days (3.3 years).
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 905 days (2.5 years); Days to treatment end: 1,207 days (3.3 years).
   Treatment given: Therapeutic agents: Dexamethasone + Ixazomib + Lenalidomide; Regimen or line of therapy: Third line of therapy; Days to treatment start: 1,248 days (3.4 years); Days to treatment end: 1,418 days (3.9 years).
   Treatment given: Therapeutic agents: Pomalidomide; Regimen or line of therapy: Fourth line of therapy; Days to treatment start: 1,418 days (3.9 years); Days to treatment end: 1,448 days (4.0 years).
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone; Regimen or line of therapy: Fourth line of therapy; Days to treatment start: 1,428 days (3.9 years); Days to treatment end: 1,443 days (4.0 years).
   Treatment given: Therapeutic agents: Daratumumab + Dexamethasone; Regimen or line of therapy: Fifth line of therapy; Days to treatment start: 1,449 days (4.0 years); Days to treatment end: 1,578 days (4.3 years).
   Treatment given: Therapeutic agents: Thalidomide; Regimen or line of therapy: Fifth line of therapy; Days to treatment start: 1,449 days (4.0 years); Days to treatment end: 1,554 days (4.3 years).
   Treatment given: Therapeutic agents: Prednisone; Regimen or line of therapy: Fifth line of therapy; Days to treatment start: 1,452 days (4.0 years); Days to treatment end: 1,578 days (4.3 years).
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: Fifth line of therapy; Days to treatment start: 1,536 days (4.2 years); Days to treatment end: 1,578 days (4.3 years).
   Treatment given: Therapeutic agents: Pomalidomide; Regimen or line of therapy: Fifth line of therapy; Days to treatment start: 1,564 days (4.3 years); Days to treatment end: 1,578 days (4.3 years).
   Treatment given: Therapeutic agents: Bendamustine + Carfilzomib + Dexamethasone; Regimen or line of therapy: Sixth line of therapy; Days to treatment start: 1,589 days (4.4 years); Days to treatment end: 1,590 days (4.4 years).
   Treatment given: Therapeutic agents: Pomalidomide; Regimen or line of therapy: Seventh line of therapy; Days to treatment start: 1,610 days (4.4 years); Days to treatment end: 1,666 days (4.6 years).
   Treatment given: Therapeutic agents: Dexamethasone + Other; Regimen or line of therapy: Seventh line of therapy; Days to treatment start: 1,617 days (4.4 years); Days to treatment end: 1,666 days (4.6 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -11 (ECOG 1): M Protein 4.33 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.739 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.04 mg/dL; Immunoglobulin G 4.07 g/L; Immunoglobulin A 59.8 g/L; Immunoglobulin M 0.21 g/L; Beta 2 Microglobulin 7.19 µg/mL; Lactate Dehydrogenase 2.42 µkat/L; Hemoglobin 5.46 mmol/L; Leukocytes 8.9 ×10⁹/L; Absolute Neutrophil 6.3 ×10⁹/L; Platelets 241 ×10⁹/L; Creatinine 101 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.6 mmol/L; Albumin 34 g/L; Total Protein 9.6 g/dL; Glucose 4.18 mmol/L.
- Day 79 (ECOG 0): M Protein 0.11 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.983 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 7.7 mg/dL; Immunoglobulin G 5.26 g/L; Immunoglobulin A 1.18 g/L; Immunoglobulin M 0.23 g/L; Beta 2 Microglobulin 2.38 µg/mL; Lactate Dehydrogenase 8.34 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 9.9 ×10⁹/L; Absolute Neutrophil 6.8 ×10⁹/L; Platelets 158 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.2 mmol/L; Albumin 40 g/L; Total Protein 6.5 g/dL; Glucose 6.66 mmol/L.
- Day 171 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.802 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.623 mg/dL; Immunoglobulin G 6.83 g/L; Immunoglobulin A 0.37 g/L; Immunoglobulin M 0.13 g/L; Beta 2 Microglobulin 3.22 µg/mL; Lactate Dehydrogenase 3.32 µkat/L; Hemoglobin 6.45 mmol/L; Leukocytes 10 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 169 ×10⁹/L; Creatinine 80.4 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.3 mmol/L; Albumin 42 g/L; Total Protein 6.1 g/dL; Glucose 6.88 mmol/L.
- Day 276 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.03 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.658 mg/dL; Immunoglobulin G 5.57 g/L; Immunoglobulin A 0.12 g/L; Immunoglobulin M 0.18 g/L; Beta 2 Microglobulin 2.09 µg/mL; Lactate Dehydrogenase 2.72 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 9.2 ×10⁹/L; Absolute Neutrophil 4.5 ×10⁹/L; Platelets 154 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.38 mmol/L; Albumin 49 g/L; Total Protein 6.5 g/dL; Glucose 5.39 mmol/L.
- Day 367 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.776 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.02 mg/dL; Immunoglobulin G 5.69 g/L; Immunoglobulin A 0.12 g/L; Immunoglobulin M 0.24 g/L; Beta 2 Microglobulin 1.64 µg/mL; Hemoglobin 7.07 mmol/L; Leukocytes 7.9 ×10⁹/L; Absolute Neutrophil 4.5 ×10⁹/L; Platelets 159 ×10⁹/L.
- Day 473 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.937 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.888 mg/dL; Immunoglobulin G 6.86 g/L; Immunoglobulin A 0.27 g/L; Immunoglobulin M 1.27 g/L; Lactate Dehydrogenase 3.27 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 8.9 ×10⁹/L; Absolute Neutrophil 4.7 ×10⁹/L; Platelets 166 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.33 mmol/L; Albumin 46 g/L; Total Protein 6.6 g/dL; Glucose 5.72 mmol/L.
- Day 549 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.915 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.883 mg/dL; Immunoglobulin G 7.39 g/L; Immunoglobulin A 0.35 g/L; Immunoglobulin M 0.85 g/L; Lactate Dehydrogenase 3.17 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 9.2 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 168 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.35 mmol/L; Albumin 46 g/L; Total Protein 6.7 g/dL; Glucose 4.51 mmol/L.
- Day 633 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.996 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.03 mg/dL; Immunoglobulin G 6.9 g/L; Immunoglobulin A 0.39 g/L; Immunoglobulin M 0.85 g/L; Lactate Dehydrogenase 2.67 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 9.2 ×10⁹/L; Absolute Neutrophil 5.1 ×10⁹/L; Platelets 169 ×10⁹/L; Creatinine 80.4 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.33 mmol/L; Albumin 47 g/L; Total Protein 6.4 g/dL; Glucose 5.06 mmol/L.
- Day 696 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.845 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.88 mg/dL; Immunoglobulin G 7.35 g/L; Immunoglobulin A 0.44 g/L; Immunoglobulin M 0.99 g/L; Lactate Dehydrogenase 2.72 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 9.2 ×10⁹/L; Absolute Neutrophil 5.1 ×10⁹/L; Platelets 169 ×10⁹/L; Creatinine 173 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.38 mmol/L; Albumin 47 g/L; Total Protein 6.6 g/dL; Glucose 6.11 mmol/L.
- Day 787 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.856 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.927 mg/dL; Immunoglobulin G 6.98 g/L; Immunoglobulin A 0.63 g/L; Immunoglobulin M 0.91 g/L; Lactate Dehydrogenase 3.9 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 9.4 ×10⁹/L; Absolute Neutrophil 5.4 ×10⁹/L; Platelets 174 ×10⁹/L; Creatinine 85.7 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.43 mmol/L; Albumin 47 g/L; Total Protein 6.6 g/dL; Glucose 5.12 mmol/L.
- Day 898 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.425 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.76 mg/dL; Immunoglobulin G 6.72 g/L; Immunoglobulin A 1.26 g/L; Immunoglobulin M 0.55 g/L; Lactate Dehydrogenase 14.3 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 8.8 ×10⁹/L; Absolute Neutrophil 4.8 ×10⁹/L; Platelets 167 ×10⁹/L; Creatinine 82.2 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.4 mmol/L; Albumin 45 g/L; Total Protein 6.8 g/dL; Glucose 5.12 mmol/L.
- Day 995 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.01 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.635 mg/dL; Immunoglobulin G 5.27 g/L; Immunoglobulin A 0.38 g/L; Immunoglobulin M 0.78 g/L; Lactate Dehydrogenase 4.23 µkat/L; Hemoglobin 6.01 mmol/L; Leukocytes 8.3 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 258 ×10⁹/L; Creatinine 76 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.23 mmol/L; Albumin 42 g/L; Total Protein 6.6 g/dL; Glucose 6.66 mmol/L.
- Day 1,060 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.988 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.677 mg/dL; Immunoglobulin G 5.19 g/L; Immunoglobulin A 0.24 g/L; Immunoglobulin M 0.51 g/L; Lactate Dehydrogenase 3.98 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 121 ×10⁹/L; Creatinine 69.8 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.25 mmol/L; Albumin 43 g/L; Total Protein 5.9 g/dL; Glucose 4.79 mmol/L.
- Day 1,144 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.17 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.17 mg/dL; Immunoglobulin G 5.44 g/L; Immunoglobulin A 0.22 g/L; Immunoglobulin M 0.39 g/L; Lactate Dehydrogenase 4.67 µkat/L; Hemoglobin 6.14 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 155 ×10⁹/L; Creatinine 67.2 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.3 mmol/L; Albumin 42 g/L; Total Protein 6 g/dL; Glucose 6.55 mmol/L.
- Day 1,262 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.632 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 9.84 mg/dL; Immunoglobulin G 5.76 g/L; Immunoglobulin A 0.16 g/L; Immunoglobulin M 0.18 g/L; Lactate Dehydrogenase 7.57 µkat/L; Hemoglobin 5.89 mmol/L; Leukocytes 6.8 ×10⁹/L; Absolute Neutrophil 5.5 ×10⁹/L; Platelets 126 ×10⁹/L; Creatinine 87.5 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.3 mmol/L; Albumin 45 g/L; Total Protein 6.5 g/dL; Glucose 7.37 mmol/L.
- Day 1,346 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.15 mg/dL; Immunoglobulin G 5.47 g/L; Immunoglobulin A 0.18 g/L; Immunoglobulin M 0.21 g/L; Lactate Dehydrogenase 2.72 µkat/L; Hemoglobin 6.45 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 107 ×10⁹/L; Creatinine 84.9 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.15 mmol/L; Albumin 41 g/L; Total Protein 5.9 g/dL; Glucose 6.33 mmol/L.
- Day 1,449 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.611 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 7.31 mg/dL; Immunoglobulin G 3.13 g/L; Immunoglobulin A 0.12 g/L; Immunoglobulin M 0.14 g/L; Lactate Dehydrogenase 4.5 µkat/L; Hemoglobin 5.52 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1 ×10⁹/L; Platelets 27 ×10⁹/L; Creatinine 93.7 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.03 mmol/L; Albumin 36 g/L; Total Protein 5.2 g/dL; Glucose 5.45 mmol/L.
- Day 1,536 (ECOG 1): M Protein 0.09 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.31 mg/dL; Immunoglobulin G 2.16 g/L; Immunoglobulin A 0.05 g/L; Immunoglobulin M 0.06 g/L; Lactate Dehydrogenase 3.63 µkat/L; Hemoglobin 5.33 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 0.6 ×10⁹/L; Platelets 83 ×10⁹/L; Creatinine 73.4 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.13 mmol/L; Albumin 36 g/L; Total Protein 5.4 g/dL; Glucose 6.82 mmol/L.
- Day 1,617 (ECOG 1): M Protein 0.07 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.72 mg/dL; Immunoglobulin G 1.8 g/L; Immunoglobulin A 0.07 g/L; Immunoglobulin M 0.05 g/L; Hemoglobin 5.52 mmol/L; Leukocytes 7.1 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 96 ×10⁹/L; Creatinine 55.7 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.25 mmol/L; Albumin 35 g/L; Total Protein 5.5 g/dL; Glucose 6.27 mmol/L.

Other clinical attributes
- Day -11: Weight: 88 kg; Height: 180 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling.

Biospecimens (2 samples)
- Sample MMRF_1257_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -11 days.
- Sample MMRF_1257_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -11 days.
